Somatic mutation profile of tumor specimen TCGA-DJ-A2PW-01A (aliquot TCGA-DJ-A2PW-01A-11D-A19J-08) from TCGA case TCGA-DJ-A2PW, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 65.7 years (23,987 days).
Specimen TCGA-DJ-A2PW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6da7e3e2-f240-49b2-b872-3e8d75f2438c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A2PW-10A (Blood Derived Normal), aliquot TCGA-DJ-A2PW-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3a8ad567-ed58-429f-a219-67352809fa00

The open-access MAF lists 14 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 9, Silent 2, Nonsense Mutation 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CSMD3 | c.5671G>A p.G1891S (on ENST00000297405 / NM_001363185.1; = p.G1787S on NM_052900.3) | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV52332684; called by muse, mutect2, varscan2
- HOOK3 | c.695C>G p.S232C | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1403721030, COSV56888359; called by muse, mutect2, varscan2
- KMT2C | c.10771C>T p.Q3591* | Nonsense Mutation (SNP) | VAF 6/71 reads (8%) | catalogued as COSV51507922; called by muse, mutect2
- MINDY2 | c.1171G>A p.V391M | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV57508947; called by muse, mutect2
- OTOA | c.1115A>G p.H372R (on ENST00000286149; = p.H358R on NM_144672.4) | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as COSV53748645, COSV99626118; called by muse, mutect2, varscan2
- PEAK1 | c.143A>G p.N48S | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs780505404, COSV56944026; called by muse, mutect2, varscan2
- PEX7 | c.217G>A p.V73M | Missense Mutation (SNP) | VAF 18/197 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs766704570, COSV59252208; called by muse, mutect2, varscan2
- PPAT | c.101C>T p.T34I | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as COSV51706141; called by muse, mutect2, varscan2
- TRPM4 | c.3283C>T p.R1095* | Nonsense Mutation (SNP) | VAF 8/61 reads (13%) | catalogued as COSV53269294; called by muse, mutect2, varscan2
- ZNF345 | c.323A>T p.H108L | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59325454; called by muse, mutect2, varscan2
- PPM1D | c.1724_1725del p.S575Cfs*2 | Frame Shift Del (DEL) | VAF 21/96 reads (22%) | called by pindel, varscan2
- FHL3 | c.72C>T p.S24= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as rs767424315, COSV65952683; called by muse, mutect2, varscan2
- TNRC6B | c.5463A>T p.L1821= (on ENST00000454349 / NM_001162501.2; = p.L1711= on NM_015088.3) | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as COSV57305810; called by muse, mutect2
